Somatic mutation profile of tumor specimen TCGA-A5-A0VO-01A (aliquot TCGA-A5-A0VO-01A-21D-A10G-09) from TCGA case TCGA-A5-A0VO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 64.5 years (23,547 days).
Specimen TCGA-A5-A0VO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42535ec6-0e73-4e6d-a041-e52d4f1f38fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0VO-10A (Blood Derived Normal), aliquot TCGA-A5-A0VO-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b078fbb-a429-405d-a3c6-cca8862b5ee9

The open-access MAF lists 80 somatic variants for this specimen: 54 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 25, Nonsense Mutation 6, Frame Shift Del 3, In Frame Del 2, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 23/88 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 94/250 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1200_1217del p.V401_N406del (on ENST00000521381 / NM_181523.3; = p.V131_N136del on NM_181504.4) | In Frame Del (DEL) | VAF 24/90 reads (27%) | hotspot (GDC flag); catalogued as COSV57141388; called by mutect2, pindel, varscan2
- ABL1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs369393102; called by muse, mutect2, varscan2
- ARAP3 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV53355417; called by muse, mutect2, varscan2
- BTBD9 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.996); catalogued as COSV58437114; called by muse, mutect2, varscan2
- CAMTA2 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.06); catalogued as COSV61838741; called by muse, mutect2, varscan2
- CCDC148 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV51771872; called by muse, mutect2, varscan2
- CDH1 | c.1711+1del | Frame Shift Del (DEL) | VAF 14/115 reads (12%) | catalogued as COSV55745630; called by mutect2, pindel, varscan2
- CETN1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV59120846; called by muse, mutect2, varscan2
- CFAP251 | c.1270-1G>A p.X424_splice | Splice Site (SNP) | VAF 113/352 reads (32%) | catalogued as rs150901834, COSV56616526; called by muse, mutect2, varscan2
- CTCF | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as COSV50531229; called by muse, mutect2, varscan2
- CUL9 | c.4951C>T p.Q1651* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | catalogued as COSV52735728; called by muse, mutect2
- CX3CR1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.086); catalogued as COSV64195570; called by muse, mutect2, varscan2
- ENPP5 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868371687, COSV57910219; called by muse, mutect2, varscan2
- GEN1 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV58058796; called by muse, mutect2
- GLG1 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 64/170 reads (38%) | catalogued as rs778749401, COSV52671014; called by muse, mutect2, varscan2
- HTR5A | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as rs1461352395, COSV55283384, COSV55284497; called by muse, mutect2, varscan2
- IL12RB2 | c.1502C>A p.A501E | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52027874; called by muse, mutect2
- KANK1 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs17853808, COSV63216725; called by muse, mutect2, varscan2
- KLHL40 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV55137553; called by muse, mutect2, varscan2
- KNTC1 | c.5005A>G p.K1669E | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV61084927; called by muse, varscan2
- MAGEC2 | c.75G>T p.W25C | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV55999103; called by muse, mutect2, varscan2
- NECTIN1 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs200181526, COSV50609584; called by muse, mutect2, varscan2
- NRG1 | c.1867G>A p.E623K (on ENST00000405005 / NM_013964.5; = p.E628K on NM_013956.5) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV55177817; called by muse, mutect2, varscan2
- NUP160 | c.1630C>T p.H544Y | Missense Mutation (SNP) | VAF 111/276 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV65856342; called by muse, mutect2, varscan2
- OR10J3 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.365); catalogued as rs762786872, COSV59955799; called by muse, mutect2, varscan2
- OR7D4 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs775480123, COSV58071313; called by muse, mutect2, varscan2
- PCDHAC1 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.811); catalogued as rs1377533547, COSV53872973; called by muse, mutect2, varscan2
- PDIA6 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs571578605, COSV55349664; called by muse, mutect2, varscan2
- PPL | c.5177A>G p.Q1726R | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52173639; called by muse, mutect2
- PTPRZ1 | c.4995C>A p.C1665* | Nonsense Mutation (SNP) | VAF 40/230 reads (17%) | catalogued as COSV66446653; called by muse, mutect2, varscan2
- RC3H1 | c.3334G>A p.D1112N | Missense Mutation (SNP) | VAF 87/236 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as rs774947144, COSV51221452; called by muse, mutect2, varscan2
- RNF111 | c.1531C>T p.H511Y | Missense Mutation (SNP) | VAF 85/225 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); catalogued as rs1212343247, COSV62090258; called by muse, mutect2, varscan2
- S1PR2 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300398049, COSV58486020; called by muse, mutect2, varscan2
- SCN1A | c.2722G>A p.G908S (on ENST00000303395 / NM_001202435.3; = p.G897S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs796052984, COSV57670757; called by muse, mutect2, varscan2
- SCUBE2 | c.2509A>G p.R837G (on ENST00000649792 / NM_001367977.2; = p.R780G on NM_020974.3) | Missense Mutation (SNP) | VAF 95/227 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.346); catalogued as COSV58547207; called by muse, mutect2, varscan2
- SLC26A11 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs570193518, COSV63280398, COSV63280926; called by muse, mutect2, varscan2
- SORBS1 | c.3119G>T p.W1040L | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53366910; called by muse, mutect2, varscan2
- TMC4 | c.419G>A p.R140Q (on ENST00000617472 / NM_001145303.3; = p.R134Q on NM_144686.4) | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs770000516, COSV55474443; called by muse, mutect2, varscan2
- TNC | c.6098G>A p.R2033H | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs112853515, COSV60790736; called by muse, mutect2, varscan2
- TNR | c.678C>A p.S226R | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as COSV54916903, COSV99689874; called by muse, mutect2, varscan2
- TRPC7 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs1370899715, COSV61457865; called by muse, mutect2, varscan2
- TTC16 | c.2448C>A p.S816R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV60162340; called by muse, mutect2
- TYW1 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144746147; called by muse, mutect2, varscan2
- USP31 | c.2261C>T p.T754M | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs766847677, COSV54851860; called by muse, mutect2, varscan2
- WNT8B | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59326952; called by muse, mutect2, varscan2
- ZMYM2 | c.926C>A p.S309* | Nonsense Mutation (SNP) | VAF 81/205 reads (40%) | catalogued as COSV67038052; called by muse, mutect2, varscan2
- ZNF576 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.598); catalogued as rs772352799, COSV60670475; called by muse, mutect2, varscan2
- ABRA | c.781_783del p.K261del | In Frame Del (DEL) | VAF 49/187 reads (26%) | called by mutect2, pindel, varscan2
- ARID5B | c.1333_1345del p.K445Lfs*30 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- POLR2A | c.3034+1G>T p.X1012_splice | Splice Site (SNP) | VAF 53/117 reads (45%) | called by muse, mutect2, varscan2
- PTEN | c.350_360del p.N117Sfs*5 | Frame Shift Del (DEL) | VAF 151/230 reads (66%) | called by mutect2, pindel, varscan2
- TRAV3 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 38/116 reads (33%) | called by muse, mutect2, varscan2
- CARNS1 | c.138G>A p.P46= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs566809895, COSV57132576; called by muse, mutect2, varscan2
- CHRNA2 | c.288C>T p.I96= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs561008438, COSV53560055; called by muse, mutect2, varscan2
- CYLC1 | c.1776G>C p.G592= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV61411208, COSV61416501; called by muse, mutect2, varscan2
- DPYSL3 | c.1299C>A p.I433= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV58331687; called by muse, mutect2, varscan2
- FBN1 | c.2979C>T p.C993= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as rs150126098; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FMO5 | c.318A>T p.R106= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as rs1553924842, COSV54211195; called by muse, mutect2, varscan2
- GLP1R | c.456C>T p.Y152= | Silent (SNP) | VAF 74/206 reads (36%) | catalogued as rs200564025, COSV64714685; called by muse, mutect2, varscan2
- GPR31 | c.144G>A p.P48= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs575627973, COSV100834146, COSV64762049; called by muse, mutect2, varscan2
- GSPT2 | c.252C>T p.A84= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs372010626, COSV61215336; called by muse, mutect2
- HEPACAM2 | c.129C>T p.G43= (on ENST00000394468 / NM_001039372.4; = p.G31= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/206 reads (39%) | catalogued as rs1362751035, COSV59059852, COSV59060332; called by muse, mutect2, varscan2
- IFT46 | c.306C>T p.F102= (on ENST00000264021 / NM_001168618.2; = p.F153= on NM_020153.3) | Silent (SNP) | VAF 64/160 reads (40%) | catalogued as COSV50595554; called by muse, mutect2, varscan2
- NFE2L1 | c.660C>T p.G220= | Silent (SNP) | VAF 61/158 reads (39%) | catalogued as rs761037568, COSV62583848; called by muse, mutect2, varscan2
- OTP | c.387C>T p.P129= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV60570126; called by muse, mutect2, varscan2
- PCDHB2 | c.1428C>T p.S476= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as rs1554271431, COSV50638954; called by muse, varscan2
- PLD1 | c.1260C>T p.Y420= | Silent (SNP) | VAF 67/178 reads (38%) | catalogued as COSV60574881; called by muse, mutect2, varscan2
- POM121 | c.2940G>A p.P980= (on ENST00000434423; = p.P715= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs781928772, COSV57521332; called by muse, mutect2, varscan2
- POU4F1 | c.1095C>T p.P365= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV65885159; called by muse, mutect2, varscan2
- PPP2R5B | c.324C>T p.N108= | Silent (SNP) | VAF 74/192 reads (39%) | catalogued as rs570547041, COSV51213957; called by muse, mutect2, varscan2
- RPL3L | c.933C>A p.A311= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV51908694; called by muse, mutect2
- SEMA6D | c.2430G>A p.P810= (on ENST00000316364 / NM_153618.2; = p.P748= on NM_020858.2) | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs144939945; called by muse, mutect2, varscan2
- SGK2 | c.456G>A p.R152= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV58315534; called by muse, mutect2, varscan2
- SUSD5 | c.435G>A p.S145= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs768307251, COSV58879110; called by muse, mutect2, varscan2
- SYCN | c.222C>T p.A74= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV59213233; called by mutect2, varscan2
- USH2A | c.4503G>A p.Q1501= | Silent (SNP) | VAF 72/231 reads (31%) | catalogued as COSV56447783; called by muse, mutect2
- ZSWIM4 | c.2286C>T p.C762= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1376829891, COSV54326614; called by muse, mutect2, varscan2
- MIR588 | n.67C>A | RNA (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2, varscan2
